Surgical pathology report (de-identified scan), TCGA case TCGA-4Z-AA7S, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-4Z-AA7S-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

CHF ICD-O-3
Carcinoma, urothelial papillary
8120/3
path Carcinoma, urothelial NOS
8120/3
Site: Bladder NOS C67.9
JTS 3/18/14

PATHOLOGY REPORT:

PRIMARY SITE: Bladder

1 - "Right ureteral margin" (separately):

. Free of neoplastic involvement.

2 - "Bladder + prostate":

. Invasive urothelial carcinoma of high-grade

. Size of tumor : 5.0 x 3.5 x 2.0 cm

. Depth of infiltration: it touches muscularis propria.

. Sanguineous vascular invasion: not detected

. Lymphatic vascular invasion: not detected

. Perineural invasion: not detected

. Prostate: compromised by neoplasia.

. Right and left seminal vesicles: free of neoplastic involvement

. Surgical margins free of neoplasia, right and left ureteral margins compromised by neoplasia.

- Margin of bladder wall free of neoplasia.

. 1 lymph node was dissected, being free of neoplastic involvement (0/1).

3 - "Right side margin":

. Free of neoplastic involvement.

4 - "Right lymphadenectomy":

. Free of neoplastic involvement (0/8).

5 - "Left lymphadenectomy":

. Free of neoplastic involvement (0/14).

Note : reviewing slides from other exam, invasion of muscularis propria of the bladder was detected.

Source: NCI Genomic Data Commons file a670e797-397a-48f6-9f6a-ce9563719fec (TCGA-4Z-AA7S.A406A3F6-80CB-48D6-A129-2837504B5DE2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).